CPTAC case C1245129 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): sample procurement.
https://portal.gdc.cancer.gov/cases/6cd85f15-79df-45b5-acda-b938eb35fccb

Demographics
Sex at birth: male; Age at index: 43 years; Vital status: Dead; Days to death: 598 days (1.6 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Temporal lobe; Site of resection or biopsy: Temporal lobe; Tumor grade: G4; Residual disease: R2; Last known disease status: With tumor; Days to last known disease status: 598 days (1.6 years); Progression or recurrence: yes; Days to recurrence: 322 days; Tumor focality: Unifocal.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Pack years smoked: 0; Cigarettes per day: 0; Alcohol history: Yes.

Biospecimens (8 samples)
- Samples 1104788, 1105251, SM-JU33A (3 with the same recorded description): Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
- Samples 1105256, SM-JU33M (2 with the same recorded description): Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 1105282: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Sample C1245129-TP: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen.
- Sample C1245129-TR1: Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Right; Preservation method: Snap Frozen.
